Somatic mutation profile of tumor specimen 0DMBM9 from CCDI case PBCAEG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Head, face or neck, NOS; Age at diagnosis: 10.8 years (3,953 days).
Specimen 0DMBM9: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f469fcc4-dbd6-4b54-821a-8e697ae497d7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DMBLG (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/15b13133-662f-4781-8101-d583a1dff4f6

The open-access MAF lists 90 somatic variants for this specimen: 64 protein-altering or splice-affecting, 19 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 54, Silent 19, Frame Shift Del 4, Intron 3, 5'UTR 3, Splice Region 2, Nonsense Mutation 2, Splice Site 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 183/711 reads (26%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- ACAP3 | c.1408-5G>A | Splice Region (SNP) | VAF 378/678 reads (56%) | catalogued as rs771834099; called by muse, mutect2, varscan2
- ADGRF4 | c.425A>G p.D142G | Missense Mutation (SNP) | VAF 226/658 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs757371905; called by muse, mutect2, varscan2
- CBWD1 | c.166A>G p.T56A | Missense Mutation (SNP) | VAF 75/351 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); catalogued as rs1203001596; called by muse, mutect2, varscan2
- CCDC144A | c.64G>A p.A22T | Missense Mutation (SNP) | VAF 163/413 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.499); catalogued as rs1418241760, COSV61405402; called by muse, mutect2, varscan2
- CLCA4 | c.2387G>A p.S796N | Missense Mutation (SNP) | VAF 175/457 reads (38%) | SIFT tolerated (0.95); PolyPhen benign (0.012); catalogued as COSV100991245; called by muse, mutect2, varscan2
- CNGB3 | c.1627G>T p.V543F | Missense Mutation (SNP) | VAF 125/1095 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); catalogued as rs746817996, COSV100181307, COSV60687692; called by mutect2, varscan2
- COCH | c.1346G>A p.R449H (on ENST00000216361 / NM_001347720.1; = p.R384H on NM_004086.3) | Missense Mutation (SNP) | VAF 266/628 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.073); catalogued as rs545418366, COSV53550627; called by muse, mutect2, varscan2
- FLOT2 | c.579+1G>A p.X193_splice | Splice Site (SNP) | VAF 140/499 reads (28%) | catalogued as rs749688498; called by muse, mutect2, varscan2
- GPS1 | c.1148C>T p.S383L | Missense Mutation (SNP) | VAF 128/324 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.286); catalogued as rs764924919; called by muse, mutect2, varscan2
- LDHAL6A | c.295C>T p.R99C | Missense Mutation (SNP) | VAF 279/522 reads (53%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.989); catalogued as rs201761125; called by muse, mutect2, varscan2
- NCAPG2 | c.862G>A p.D288N | Missense Mutation (SNP) | VAF 31/944 reads (3%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV99317621; called by muse, mutect2
- NIPAL4 | c.53C>A p.S18Y | Missense Mutation (SNP) | VAF 190/509 reads (37%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.001); catalogued as rs757392707; called by muse, mutect2, varscan2
- OR4C3 | c.596C>A p.A199D | Missense Mutation (SNP) | VAF 147/560 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs146984127; called by muse, mutect2, varscan2
- OR5B3 | c.23C>A p.T8K | Missense Mutation (SNP) | VAF 19/635 reads (3%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.077); catalogued as rs1469208062, COSV100511869; called by muse, mutect2
- PRDM14 | c.1613G>A p.R538H | Missense Mutation (SNP) | VAF 157/1155 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as rs777306806, COSV52573064; called by muse, mutect2, varscan2
- RAP1B | c.53C>G p.A18G | Missense Mutation (SNP) | VAF 179/589 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99164970; called by muse, mutect2, varscan2
- SCNN1A | c.1540G>A p.V514I | Missense Mutation (SNP) | VAF 234/834 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs770217992, COSV57435911; called by muse, mutect2, varscan2
- SNED1 | c.2539G>A p.G847S | Missense Mutation (SNP) | VAF 250/1024 reads (24%) | SIFT tolerated (0.53); PolyPhen benign (0.36); catalogued as rs752079033; called by muse, mutect2, varscan2
- SPATA31D4 | c.2132G>A p.R711H | Missense Mutation (SNP) | VAF 38/144 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs776047598; called by mutect2, varscan2
- SPTBN2 | c.1415C>T p.T472M | Missense Mutation (SNP) | VAF 171/557 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs561053672, CM127036, COSV59458506; called by muse, mutect2, varscan2
- STEAP2 | c.1204G>A p.A402T | Missense Mutation (SNP) | VAF 120/513 reads (23%) | SIFT tolerated (0.8); PolyPhen possibly damaging (0.481); catalogued as rs902292884, COSV99840407; called by muse, mutect2, varscan2
- TAF5 | c.2384G>A p.G795E | Missense Mutation (SNP) | VAF 303/365 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58916405; called by muse, mutect2, varscan2
- TOGARAM1 | c.4517G>A p.R1506H | Missense Mutation (SNP) | VAF 128/354 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1486568080; called by muse, mutect2, varscan2
- TP53 | c.497C>A p.S166* | Nonsense Mutation (SNP) | VAF 226/566 reads (40%) | catalogued as COSV52661795, COSV52683537, COSV52718793; called by muse, mutect2, varscan2
- WNK3 | c.4795C>T p.R1599C | Missense Mutation (SNP) | VAF 200/234 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs782572831, COSV100671584; called by muse, mutect2, varscan2
- ZNF716 | c.20C>A p.P7H | Missense Mutation (SNP) | VAF 227/1074 reads (21%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.031); catalogued as COSV70779824; called by muse, mutect2, varscan2
- ABRAXAS1 | c.412A>C p.S138R | Missense Mutation (SNP) | VAF 170/375 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- ADGRB1 | c.908T>A p.L303Q | Missense Mutation (SNP) | VAF 126/876 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- AKR1C2 | c.721C>A p.L241I | Missense Mutation (SNP) | VAF 243/810 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- AKR1C3 | c.721C>A p.L241I | Missense Mutation (SNP) | VAF 373/646 reads (58%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- ANKZF1 | c.-30-2A>G | Splice Site (SNP) | VAF 135/592 reads (23%) | called by muse, mutect2, varscan2
- ATP1A1 | c.220_221del p.D75Wfs*13 | Frame Shift Del (DEL) | VAF 170/712 reads (24%) | called by pindel, varscan2
- CFAP46 | c.1757_1758del p.K586Sfs*22 | Frame Shift Del (DEL) | VAF 172/271 reads (63%) | called by mutect2, pindel, varscan2
- CFAP47 | c.7970A>G p.K2657R | Missense Mutation (SNP) | VAF 153/183 reads (84%) | SIFT tolerated (0.6); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- COL7A1 | c.6511G>T p.G2171C | Missense Mutation (SNP) | VAF 232/769 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CXCL1 | c.91C>T p.R31C | Missense Mutation (SNP) | VAF 249/607 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DOCK10 | c.2391C>G p.H797Q | Missense Mutation (SNP) | VAF 44/940 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.087); called by muse, mutect2
- EIF2S3B | c.1383G>T p.K461N | Missense Mutation (SNP) | VAF 68/198 reads (34%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); called by muse, mutect2
- FAM126A | c.359C>A p.T120N | Missense Mutation (SNP) | VAF 97/539 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM131A | c.529A>G p.T177A (on ENST00000310585; = p.T208A on NM_144635.5) | Missense Mutation (SNP) | VAF 176/596 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- HPX | c.104T>A p.V35D | Missense Mutation (SNP) | VAF 95/378 reads (25%) | SIFT tolerated (0.6); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- INTS6L | c.119C>G p.A40G | Missense Mutation (SNP) | VAF 118/148 reads (80%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- KRT15 | c.512C>T p.T171I | Missense Mutation (SNP) | VAF 146/341 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- MRPL1 | c.332T>A p.I111N | Missense Mutation (SNP) | VAF 225/525 reads (43%) | SIFT tolerated (0.49); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- NEDD8 | c.144G>C p.K48N | Missense Mutation (SNP) | VAF 129/300 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- NIPAL1 | c.1202A>G p.D401G | Missense Mutation (SNP) | VAF 136/341 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- NLRP7 | c.407A>G p.N136S | Missense Mutation (SNP) | VAF 215/776 reads (28%) | SIFT tolerated (0.5); PolyPhen benign (0.003); called by muse, mutect2
- OR4C45 | c.690A>T p.K230N | Missense Mutation (SNP) | VAF 165/639 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PAPOLG | c.123_126del p.I42Tfs*3 | Frame Shift Del (DEL) | VAF 115/626 reads (18%) | called by pindel, varscan2
- PARP14 | c.5261_5264del p.S1754* | Frame Shift Del (DEL) | VAF 166/670 reads (25%) | called by pindel, varscan2
- PCDHGA2 | c.2359A>C p.K787Q | Missense Mutation (SNP) | VAF 331/813 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- PLXNA1 | c.5630G>T p.R1877L | Missense Mutation (SNP) | VAF 99/403 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- PPFIA4 | c.3416C>G p.A1139G (on ENST00000447715; = p.A1140G on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 250/1242 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- PRAMEF4 | c.1412T>A p.L471Q | Missense Mutation (SNP) | VAF 129/685 reads (19%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- RAB37 | c.281G>A p.S94N (on ENST00000392613 / NM_001006638.3; = p.S87N on NM_175738.5) | Missense Mutation (SNP) | VAF 203/509 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- RGL2 | c.674C>T p.P225L | Missense Mutation (SNP) | VAF 161/580 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- SYT9 | c.841C>G p.L281V | Missense Mutation (SNP) | VAF 311/1052 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- TJP1 | c.2017+7A>T | Splice Region (SNP) | VAF 111/275 reads (40%) | called by muse, mutect2, varscan2
- TMEM50A | c.336G>T p.M112I | Missense Mutation (SNP) | VAF 322/577 reads (56%) | SIFT tolerated (0.45); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TMEM64 | c.545A>T p.N182I | Missense Mutation (SNP) | VAF 188/1281 reads (15%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TTC26 | c.591G>T p.K197N | Missense Mutation (SNP) | VAF 206/816 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TTLL7 | c.2437C>T p.Q813* | Nonsense Mutation (SNP) | VAF 166/423 reads (39%) | called by muse, mutect2, varscan2
- XIRP2 | c.92G>C p.R31P (on ENST00000628543; = p.R206P on NM_152381.6) | Missense Mutation (SNP) | VAF 30/930 reads (3%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2
- ABCC9 | c.3606G>A p.T1202= | Silent (SNP) | VAF 143/481 reads (30%) | catalogued as rs143316915; called by muse, mutect2, varscan2
- AMH | c.1368C>T p.T456= | Silent (SNP) | VAF 266/584 reads (46%) | catalogued as rs755517579; called by muse, mutect2, varscan2
- B4GALT2 | c.519G>C p.R173= | Silent (SNP) | VAF 229/572 reads (40%) | catalogued as rs758272124; called by muse, mutect2, varscan2
- BIN1 | c.543C>T p.A181= | Silent (SNP) | VAF 253/576 reads (44%) | catalogued as rs746233851; called by muse, mutect2, varscan2
- CCR1 | c.69G>A p.P23= | Silent (SNP) | VAF 176/672 reads (26%) | catalogued as rs760444180, COSV56121718; called by muse, mutect2, varscan2
- CNBD1 | c.843G>C p.S281= | Silent (SNP) | VAF 110/793 reads (14%) | catalogued as COSV73072359; called by muse, mutect2, varscan2
- CNST | c.1956C>T p.D652= | Silent (SNP) | VAF 219/1021 reads (21%) | catalogued as rs747984736; called by muse, mutect2, varscan2
- FAM166A | c.888G>A p.L296= | Silent (SNP) | VAF 162/385 reads (42%) | called by muse, mutect2, varscan2
- FRYL | c.6031T>C p.L2011= | Silent (SNP) | VAF 30/725 reads (4%) | called by muse, mutect2
- GRIK5 | c.1773G>T p.T591= | Silent (SNP) | VAF 240/681 reads (35%) | catalogued as rs759135614; called by muse, mutect2, varscan2
- KCNQ2 | c.552C>T p.A184= | Silent (SNP) | VAF 395/998 reads (40%) | catalogued as rs764119402; ClinVar: likely benign; called by muse, mutect2, varscan2
- MSRA | c.186A>G p.P62= | Silent (SNP) | VAF 103/699 reads (15%) | catalogued as rs762699105; called by muse, mutect2, varscan2
- NOS1 | c.2397G>C p.V799= | Silent (SNP) | VAF 29/282 reads (10%) | called by muse, mutect2, varscan2
- OGDHL | c.1953G>A p.L651= | Silent (SNP) | VAF 423/499 reads (85%) | called by muse, mutect2, varscan2
- PIK3AP1 | c.456C>T p.D152= | Silent (SNP) | VAF 173/449 reads (39%) | catalogued as COSV100226278; called by muse, mutect2, varscan2
- SHANK2 | c.2175C>G p.P725= | Silent (SNP) | VAF 219/770 reads (28%) | catalogued as rs546959614; called by muse, mutect2, varscan2
- SPTAN1 | c.5685C>T p.S1895= | Silent (SNP) | VAF 169/535 reads (32%) | catalogued as rs779393161; called by muse, mutect2, varscan2
- TRPM3 | c.813C>T p.V271= (on ENST00000357533 / NM_001366142.2; = p.V116= on NM_020952.6) | Silent (SNP) | VAF 102/256 reads (40%) | called by muse, mutect2, varscan2
- TUBA3C | c.675C>A p.T225= | Silent (SNP) | VAF 30/808 reads (4%) | catalogued as COSV67139210; called by muse, mutect2
- CCDC121 | c.-18G>A | 5'UTR (SNP) | VAF 498/1133 reads (44%) | catalogued as rs769354652, COSV53112398; called by muse, mutect2, varscan2
- CCDC8 | c.-60G>T | 5'UTR (SNP) | VAF 57/230 reads (25%) | called by muse, mutect2, varscan2
- CRACD | c.*6G>T | 3'UTR (SNP) | VAF 103/272 reads (38%) | called by muse, mutect2, varscan2
- MIGA1 | c.1188+93T>C | Intron (SNP) | VAF 22/49 reads (45%) | called by muse, mutect2, varscan2
- MINAR2 | c.-63A>C | 5'UTR (SNP) | VAF 12/108 reads (11%) | called by muse, mutect2
- NELFCD | c.1009-25G>T | Intron (SNP) | VAF 320/807 reads (40%) | called by muse, mutect2, varscan2
- RNF123 | c.1959+23T>A | Intron (SNP) | VAF 185/643 reads (29%) | called by muse, mutect2, varscan2
